Surgical pathology report (de-identified scan), TCGA case TCGA-HU-A4GX, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site National Cancer Center Korea, specimen TCGA-HU-A4GX-01A (Primary Tumor).

[page 1 of 4]
GROSS:

Speciment status: Fresh

Operation:

Total gastrectomy, left lateral sectionectomy of liver, cholecystectomy
and segmental resection of small intestine

Specimen submitted: Stomach, gallbaldder, small intestine and liver

Measurement:

[Stomach]

Greater curvature 33.0 cm

Lesser curvature 21.0 cm

Proximal resection margin 4.5 cm

Resection margin 6.5 cm

Esophagus 0.5 cm

Duodenum 1.0 cm

[Liver]

13.0 x 5.0 x 8.0 cm

[Gallbladder]

11.5 cm in length and 3.0 cm in diameter, 0.2 cm in thickness

[Small intestine]

5.0 cm in length and 3.0 cm in diameter

Tumor location:

Stomach: Middle to lower 1/3 (body and antrum) and lesser curvature

From proximal resection margin - 3.5 cm

From distal resection margin - 10.5 cm

Tumor size: 8.0 x 5.0 x 1.5 cm

Tumor type: AGC (Borrmann type) III

Gross serosal and hepatic invasion: Yes

Remaining tissue

Stomach: Unremarkable

Liver: Unremarkable

Gall baldder: Unremarkable

Small intestine: Unremarkable

Representative sections submitted

Blocks

T1-8 and TB, tumor and surrounding gastric tissue x 9

T9-10, tumor with liver x 2

ICD-0-3

adenocarcinoma, diffuse type 8145/3

Site: stomach, antrum C16.3

fw 9/27/12

[page 2 of 4]
NB, unremarkable stomach x 1
A, antral mucosa x 1
B, body mucosa x 1
P, proximal resection margin x 1
D, distal resection margin x 1
RM, hepatic resection margin x 1
RM1-2, separately submitted unlabeled tissue x 2
C, separate small intestine x 1
LN1-6, superior gastric lymph nodes x 6
LN7-8, inferior gastric lymph nodes x 2
LN9-10, '5' lymph nodes x 2
LN11, '6' lymph nodes x 1
LN12-3, '7' lymph nodes x 2
LN14-5, '8' lymph nodes x 2
LN16, '9' lymph nodes x 1
LN17, '11p' lymph nodes x 1
LN18, '12' lymph nodes x 1

GB, gallbladder x 1

L, liver x 1

MICROSCOPIC:

Tumor type: Adenocarcinoma - tubular, poorly differentiated

Depth of tumor invasion:

T4: T4b-Tumor invades adjacent structures (Liver)

Margins: Proximal resection margin (-)

Distal resection margin (-)

Hepatic resection margin (-)

Ming classification (Growth pattern): Infiltrative

Lymphoid reaction: Present

Lymphovascular invasion: Present

Perineural invasion: Present

Lymph node metastases:

N2: Metastasis in 3-6 regional lymph nodes

number of involved nodes 6 total number of nodes 71

perinodal extension: Yes

Distant metastasis(M): Not applicable

Pathologic stage: pT4bN2Mx (AJCC 7th edition)

[page 3 of 4]
DIAGNOSIS:

Stomach, total gastrectomy:

Adenocarcinoma, poorly differentiated, infiltrating
(advanced gastric cancer)

<Addendum>

Final diagnosis: Stomach Adenocarcinoma, Diffuse Type *per clarification by TSS.*

Liver, left lateral sectionectomy:

- Adenocarcinoma, extended from stomach
- Fatty change

Dx discrepancy form attached.

*hw
10/9/12*

Gallbladder, cholecystectomy: No tumor present

Small intestine, segmental resection: No tumor present

Lymph node, perigastric, total gastrectomy:

Superior gastric: Metastatic adenocarcinoma, primary in stomach (6/32)

Inferior gastric: No tumor present (0/10)

Lymph node, regional, biopsy:

Labeled '5': No tumor present (0/3)

Labeled '6': No tumor present (0/5)

Labeled '7': No tumor present (0/9)

Labeled '8': No tumor present (0/7)

Labeled '9': No tumor present (0/3)

Labeled '11p': No tumor present (0/0)

Labeled '12': No tumor present (0/2)

Reviewed: KML	Date Reviewed: 9/17/12	

hw 9/20/12

[page 4 of 4]
TCGA Pathologic Diagnosis Discrepancy Form

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): Stomach adenocarcinoma

Completed By (

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	P/D Tubular Adenocarcinoma, SRC componeent	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF	Stomach Adenocarcinoma, Diffuse Type	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	In the original pathology report (for the whole resected specimen), this tumor is described as poorly-differentiated adenocarcinoma with signet ring cell component. Review of TCGA sample top slide identified that this tumor is solely composed of an stomach adenocarcinoma, diffuse type and the addendum was created as such	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director		Provide the name of the pathologist who reviewed this case for TCGA

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file a9d6e3f1-557a-4790-88a8-a7d65fe2f5de (TCGA-HU-A4GX.B7205BE2-2251-4363-AC4A-8D0A482BEA72.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).